Somatic mutation profile of tumor specimen TCGA-ER-A19D-06A (aliquot TCGA-ER-A19D-06A-11D-A197-08) from TCGA case TCGA-ER-A19D, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.2 years (17,244 days).
Specimen TCGA-ER-A19D-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 692b3569-4783-44d8-afaa-e833e2641bb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19D-10A (Blood Derived Normal), aliquot TCGA-ER-A19D-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fabfb76-91d7-4921-9a90-850e4895be89

The open-access MAF lists 573 somatic variants for this specimen: 355 protein-altering or splice-affecting, 200 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 322, Silent 200, Nonsense Mutation 19, Intron 10, Splice Site 9, 3'UTR 4, Frame Shift Del 3, RNA 3, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 37/59 reads (63%) | hotspot (GDC flag); catalogued as CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; called by muse, mutect2, varscan2
- COL4A5 | c.2395+1G>A p.X799_splice | Splice Site (SNP) | VAF 54/128 reads (42%) | catalogued as rs869025331, COSV100088960; ClinVar: pathogenic; called by muse, varscan2
- MYPN | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205457, COSV62733066; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 250/328 reads (76%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCC4 | c.2425C>T p.P809S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.654); catalogued as COSV65316500; called by muse, mutect2, varscan2
- ACADM | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.618); catalogued as rs1057516485, COSV63720868; called by muse, mutect2
- ACKR1 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63674012; called by muse, mutect2, varscan2
- ADAM18 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55852001; called by muse, mutect2, varscan2
- ADAMTS16 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV57001141; called by muse, mutect2, varscan2
- ADAMTS9 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.019); catalogued as rs1231461637, COSV55787059; called by muse, mutect2, varscan2
- ADCY8 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV53920207; called by muse, mutect2, varscan2
- ADIPOQ | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57859713; called by muse, mutect2, varscan2
- ADORA1 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs199949273, COSV55143632; called by muse, mutect2, varscan2
- AGO1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64596051; called by muse, mutect2, varscan2
- AK9 | c.3624A>T p.K1208N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV58147054; called by muse, mutect2, varscan2
- AKT3 | c.1163+1G>A p.X388_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as COSV55626736; called by muse, mutect2
- ALDH2 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs764073001, COSV55669896; called by muse, mutect2
- ALDOB | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 135/345 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as rs867022678, COSV66397306; called by muse, mutect2, varscan2
- AMER1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100366174, COSV57664474; called by muse, mutect2, varscan2
- AMOT | c.1636G>A p.E546K (on ENST00000371959 / NM_001113490.1; = p.E137K on NM_133265.3) | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59063335, COSV59066702; called by muse, mutect2, varscan2
- ANK1 | c.3190G>C p.V1064L | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV55890224; called by muse, mutect2, varscan2
- ANK2 | c.3327C>G p.F1109L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.096); catalogued as COSV52160879, COSV52178738; called by muse, mutect2, varscan2
- ANKRD17 | c.5128C>G p.P1710A | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58225416; called by muse, mutect2, varscan2
- ANKRD24 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53673851, COSV99516840; called by muse, mutect2, varscan2
- APBA3 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57463454; called by muse, mutect2, varscan2
- AREG | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 110/308 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV52645065; called by muse, mutect2, varscan2
- ARSF | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63840568; called by muse, mutect2, varscan2
- ASIC2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV63321889; called by muse, mutect2, varscan2
- ASXL3 | c.6706G>A p.G2236S | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52474526; called by muse, mutect2, varscan2
- ATP1A4 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 151/241 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV63627844; called by muse, mutect2, varscan2
- ATP2B2 | c.1376C>T p.S459L (on ENST00000352432; = p.S425L on NM_001683.5) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1256194224, COSV59504191; called by muse, mutect2, varscan2
- ATP4B | c.242-1G>A p.X81_splice | Splice Site (SNP) | VAF 30/71 reads (42%) | catalogued as COSV58929533; called by muse, mutect2, varscan2
- B3GALT1 | c.628G>T p.G210* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV59909411; called by muse, mutect2, varscan2
- BRD2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs749922515, COSV66374219; called by muse, mutect2
- BRINP1 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs527860111, COSV56308793; called by muse, mutect2, varscan2
- BSN | c.9676A>T p.N3226Y | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV56524333; called by muse, mutect2, varscan2
- C12orf50 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs145797004; called by muse, mutect2, varscan2
- C1RL | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as COSV56926173; called by muse, mutect2, varscan2
- C2orf78 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as COSV68516404, COSV68518717; called by muse, mutect2, varscan2
- C7 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs753530114, COSV57477052; called by muse, mutect2, varscan2
- C8B | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV64778823; called by muse, mutect2, varscan2
- CACNA2D3 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV55565970; called by muse, mutect2, varscan2
- CARD17 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV65214814; called by muse, mutect2
- CBS | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61444646; called by mutect2, varscan2
- CCDC102B | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV60149784; called by muse, mutect2, varscan2
- CCR7 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 74/119 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55850153; called by muse, mutect2, varscan2
- CDADC1 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as rs746954267, COSV51912808; called by muse, mutect2, varscan2
- CDH2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 141/271 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52290956; called by muse, mutect2, varscan2
- CDH22 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV64837279; called by muse, mutect2, varscan2
- CDH6 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV54063332; called by muse, mutect2, varscan2
- CDK2AP1 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55543075; called by muse, mutect2, varscan2
- CDKN1A | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV55190617; called by muse, mutect2, varscan2
- CELSR3 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV50997481; called by muse, mutect2, varscan2
- CENPE | c.2710C>A p.Q904K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV54386609; called by muse, mutect2, varscan2
- CEP290 | c.6028C>T p.P2010S | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV58354354; called by muse, mutect2, varscan2
- CHD4 | c.1637C>T p.S546F (on ENST00000357008 / NM_001363606.2; = p.S559F on NM_001273.5) | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV58907626; called by muse, mutect2, varscan2
- CHGB | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV66761398; called by muse, mutect2, varscan2
- CHI3L1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV55138769; called by muse, mutect2, varscan2
- CHMP2B | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 29/62 reads (47%) | catalogued as COSV55463274; called by muse, mutect2, varscan2
- CHN1 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV55035030; called by muse, mutect2, varscan2
- CIART | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104391896, COSV51745554; called by muse, mutect2, varscan2
- CILP | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs1312103267; called by muse, mutect2, varscan2
- CLCN1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143506735, COSV58372528; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN4 | c.1682G>A p.W561* | Nonsense Mutation (SNP) | VAF 27/102 reads (26%) | catalogued as COSV66467796; called by muse, mutect2, varscan2
- CMTR1 | c.1506-1G>A p.X502_splice | Splice Site (SNP) | VAF 12/69 reads (17%) | catalogued as COSV65091344; called by muse, mutect2, varscan2
- CNTNAP5 | c.2972G>A p.G991E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70502008; called by muse, mutect2
- COL24A1 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364902021, COSV65310876; called by muse, mutect2
- COL24A1 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as rs377469635; called by muse, mutect2, varscan2
- COL2A1 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs781555326, COSV61532821; called by muse, mutect2, varscan2
- COL4A5 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60367827; called by muse, varscan2
- COL5A1 | c.2232G>A p.K744= | Splice Region (SNP) | VAF 12/52 reads (23%) | catalogued as COSV65673008; called by muse, mutect2, varscan2
- COL5A2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.783); catalogued as COSV66412835; called by muse, mutect2
- COL5A3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs780783103, COSV53408632, COSV53416377; called by muse, mutect2, varscan2
- COL9A3 | c.167G>A p.G56D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51701262; called by muse, mutect2, varscan2
- CPA1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV50573178; called by muse, mutect2, varscan2
- CPZ | c.1477G>A p.E493K (on ENST00000360986 / NM_001014447.3; = p.E482K on NM_003652.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV59922893; called by muse, mutect2, varscan2
- CRACDL | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV67409548; called by muse, mutect2, varscan2
- CSAG1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63400848; called by muse, mutect2, varscan2
- CSMD1 | c.8422C>T p.R2808C (on ENST00000520002; = p.R2807C on NM_033225.6) | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267601889, COSV59294672; called by muse, mutect2, varscan2
- CSMD2 | c.7814G>A p.R2605Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.813); catalogued as rs193921034, COSV53912174, COSV53942806; called by muse, mutect2, varscan2
- CSMD3 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as rs1274601473, COSV52100290, COSV52232006; called by muse, mutect2, varscan2
- CSTF2 | c.1525A>T p.M509L | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65894754; called by muse, mutect2, varscan2
- CTBS | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55363993; called by muse, mutect2, varscan2
- CTCFL | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs767928135, COSV54777499; called by muse, mutect2, varscan2
- CTNND2 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 39/76 reads (51%) | catalogued as COSV58884453; called by muse, mutect2, varscan2
- CYLC1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.174); catalogued as COSV61414494; called by muse, mutect2
- CYTH2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs1336327110; called by muse, mutect2, varscan2
- DCAF12L2 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV63583597; called by muse, mutect2, varscan2
- DCC | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV71438253; called by muse, mutect2, varscan2
- DDAH2 | c.275G>A p.W92* | Nonsense Mutation (SNP) | VAF 14/383 reads (4%) | catalogued as COSV65384276; called by muse, mutect2
- DDX18 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs948247921, COSV54308327; called by muse, mutect2, varscan2
- DDX43 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64837617; called by muse, mutect2, varscan2
- DEFB119 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); catalogued as COSV53619739; called by muse, mutect2, varscan2
- DENND4C | c.4077C>G p.F1359L (on ENST00000434457 / NM_001330640.2; = p.F1310L on NM_017925.7) | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs757401838, COSV63009464; called by muse, mutect2, varscan2
- DGKD | c.2659C>T p.R887* (on ENST00000264057 / NM_152879.3; = p.R843* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as rs1327372082, COSV51081125; called by muse, mutect2, varscan2
- DGKG | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs79928844, COSV53963889; called by muse, mutect2, varscan2
- DHX16 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs143108219; called by muse, mutect2, varscan2
- DLG2 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54653954; called by muse, mutect2, varscan2
- DNAH1 | c.12749G>A p.R4250Q | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs539470500, COSV56232958; called by muse, mutect2, varscan2
- DNAH5 | c.9193C>T p.P3065S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV54242797; called by muse, mutect2, varscan2
- DNAH7 | c.11891G>A p.R3964K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199830841, COSV100415811; called by muse, mutect2, varscan2
- DOCK6 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52949428; called by muse, mutect2, varscan2
- DPYS | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV60906546; called by muse, mutect2, varscan2
- DRGX | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 82/110 reads (75%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV65137148; called by muse, mutect2, varscan2
- DSC3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV64574473; called by muse, mutect2, varscan2
- EDAR | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as rs868037570, COSV51506119; called by muse, mutect2, varscan2
- EEF2 | c.615C>T p.I205= | Splice Region (SNP) | VAF 44/99 reads (44%) | catalogued as rs375130935, COSV58579656; called by muse, mutect2, varscan2
- EFR3A | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs182899732, COSV54460607, COSV99603407; called by muse, mutect2, varscan2
- EHD3 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV59032286; called by muse, mutect2, varscan2
- EHD3 | c.579A>T p.K193N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV59032294; called by muse, mutect2, varscan2
- EMD | c.541T>A p.Y181N | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV63962385; called by muse, mutect2, varscan2
- ENTPD4 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as COSV62269849; called by muse, mutect2, varscan2
- ERN2 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56836261, COSV99890900; called by muse, mutect2, varscan2
- EZHIP | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100539791; called by muse, mutect2, varscan2
- FAM227B | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV54816459; called by muse, mutect2, varscan2
- FAT3 | c.9599C>T p.S3200L | Missense Mutation (SNP) | VAF 25/372 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.476); catalogued as rs376790690; called by muse, mutect2
- FCER1A | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs751533005, COSV63666565; called by muse, mutect2, varscan2
- FMO3 | c.374G>A p.W125* | Nonsense Mutation (SNP) | VAF 16/67 reads (24%) | catalogued as COSV63007254; called by muse, mutect2, varscan2
- FMO4 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs748800692, COSV63001586; called by muse, mutect2, varscan2
- FOXD4L5 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV66240971; called by mutect2, varscan2
- FOXN1 | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV56883318, COSV99881043; called by muse, mutect2, varscan2
- FREM2 | c.1066A>G p.I356V | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV54846517; called by muse, mutect2, varscan2
- FRMD7 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 85/162 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV53748032; called by muse, mutect2, varscan2
- FUT7 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs781521197, COSV55804658; called by muse, mutect2, varscan2
- GAA | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56410720; called by muse, mutect2
- GAA | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as CM1211940, COSV56407540, COSV56408786, COSV56410737; called by muse, mutect2, varscan2
- GABRR1 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV65620134; called by muse, mutect2, varscan2
- GCLC | c.1352C>T p.T451I (on ENST00000643939; = p.T449I on NM_001498.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV57597079; called by muse, mutect2, varscan2
- GLI4 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60682154, COSV60682519; called by muse, mutect2, varscan2
- GLRB | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV52420460; called by muse, mutect2
- GPRC6A | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV59951498, COSV59955010; called by muse, mutect2, varscan2
- GRAMD1A | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.165); catalogued as COSV58768275; called by muse, mutect2, varscan2
- GRM7 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781373607, COSV63138807; called by muse, mutect2, varscan2
- GUCY2C | c.202C>G p.R68G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.209); catalogued as COSV53793837, COSV99663608; called by muse, mutect2, varscan2
- H3C3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs1422878610, COSV63550732; called by muse, mutect2, varscan2
- HCFC1 | c.4642G>A p.D1548N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); catalogued as COSV60075745; called by muse, mutect2, varscan2
- HEPACAM | c.302T>A p.L101H | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53431704; called by muse, mutect2
- HGSNAT | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV52818290; called by muse, mutect2, varscan2
- HIPK1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65784610; called by muse, mutect2, varscan2
- HIPK4 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.622); catalogued as rs767888140, COSV52521541; called by muse, mutect2, varscan2
- HNRNPL | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55494555; called by muse, mutect2, varscan2
- HSD17B11 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.393); catalogued as COSV64155008; called by muse, mutect2, varscan2
- HYDIN | c.10280C>T p.S3427F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66859649; called by muse, mutect2, varscan2
- IQGAP2 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV57178641; called by muse, mutect2, varscan2
- ITSN1 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as rs376139396; called by muse, mutect2, varscan2
- JAKMIP1 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1256558617, COSV51540721; called by muse, mutect2, varscan2
- JCAD | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 132/188 reads (70%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as rs368497057; called by muse, mutect2, varscan2
- JCAD | c.3328C>T p.Q1110* | Nonsense Mutation (SNP) | VAF 65/84 reads (77%) | catalogued as COSV64761046; called by muse, mutect2, varscan2
- JMJD4 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59919375; called by muse, mutect2, varscan2
- KCNA6 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54976775; called by muse, mutect2, varscan2
- KCNB1 | c.2045G>A p.S682N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as COSV65570101; called by muse, mutect2, varscan2
- KCND2 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58595824; called by muse, mutect2, varscan2
- KCNJ9 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63632300; called by muse, mutect2, varscan2
- KDM5C | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64767536; called by muse, mutect2, varscan2
- KIAA1217 | c.3653G>A p.W1218* | Nonsense Mutation (SNP) | VAF 21/29 reads (72%) | catalogued as COSV100287111, COSV56821018; called by muse, mutect2, varscan2
- KIF14 | c.2961+2T>C p.X987_splice | Splice Site (SNP) | VAF 28/156 reads (18%) | catalogued as COSV66263243; called by muse, mutect2, varscan2
- KIF15 | c.2550-1G>A p.X850_splice | Splice Site (SNP) | VAF 13/68 reads (19%) | catalogued as rs748859460, COSV58163618; called by muse, mutect2, varscan2
- KIR2DL3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 82/474 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as rs755633828; called by muse, varscan2
- KL | c.2311C>T p.P771S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66309588; called by muse, mutect2, varscan2
- KLHL4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs190477338, COSV64139169; called by muse, mutect2, varscan2
- KLHL4 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV64146088; called by muse, mutect2, varscan2
- KRT15 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 55/203 reads (27%) | catalogued as COSV54181108; called by muse, mutect2, varscan2
- KRT26 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs756147194, COSV100156639, COSV59415340; called by muse, mutect2, varscan2
- LAMA2 | c.3705G>A p.W1235* | Nonsense Mutation (SNP) | VAF 45/61 reads (74%) | catalogued as COSV70352703; called by muse, mutect2, varscan2
- LAMA3 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58075442; called by muse, mutect2, varscan2
- LAMC2 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV51458367; called by muse, mutect2
- LAMP5 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); catalogued as rs1467903187, COSV55717486; called by muse, mutect2, varscan2
- LILRB2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.748); catalogued as rs746485626, COSV58745250; called by muse, mutect2, varscan2
- LRP2 | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs756651134, COSV55547502; called by muse, mutect2, varscan2
- LRRC7 | c.4364C>T p.P1455L (on ENST00000651989 / NM_001370785.2; = p.P1375L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV50500457; called by muse, mutect2, varscan2
- LSM6 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56852615; called by muse, mutect2, varscan2
- MAP1B | c.5677G>A p.E1893K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV57103622; called by muse, mutect2, varscan2
- MCHR2 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.023); catalogued as rs193149101, COSV56000825; called by muse, mutect2, varscan2
- MEAK7 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV59145013; called by muse, mutect2, varscan2
- MED12 | c.4282G>A p.V1428M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV61350871; called by muse, mutect2, varscan2
- MELTF | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373500136; called by muse, mutect2, varscan2
- MERTK | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.183); catalogued as COSV54933433; called by muse, mutect2, varscan2
- MEX3C | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1282529961; called by muse, mutect2, varscan2
- MIP | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57513921; called by muse, mutect2, varscan2
- MMEL1 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1437631747, COSV56524629; called by muse, mutect2, varscan2
- MMS22L | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.085); catalogued as COSV51524541; called by muse, mutect2, varscan2
- MSH6 | c.2030G>T p.S677I | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.532); catalogued as COSV52284839; called by muse, mutect2, varscan2
- MSRA | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752483444; called by muse, mutect2, varscan2
- MTIF2 | c.1790A>T p.K597I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV55053208; called by muse, mutect2, varscan2
- MTTP | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778958930, COSV55508657; called by muse, mutect2, varscan2
- MYH15 | c.5008G>A p.D1670N | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56309053, COSV56316166; called by muse, mutect2, varscan2
- MYLK3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs779225675, COSV67365877; called by muse, mutect2, varscan2
- MYO18B | c.7453C>T p.L2485F | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV59143449; called by muse, mutect2, varscan2
- MYO9B | c.3871C>T p.P1291S | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs866011945, COSV68281727; called by muse, mutect2, varscan2
- MYOCD | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.725); catalogued as rs777004853, COSV58508897; called by muse, mutect2, varscan2
- MYOM2 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs370717749; called by muse, mutect2, varscan2
- NANOS3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 90/154 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59248643; called by muse, mutect2, varscan2
- NEBL | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1188459712, COSV65804864; called by muse, mutect2, varscan2
- NEBL | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV65804867; called by muse, mutect2, varscan2
- NEK2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs988167642; called by muse, mutect2, varscan2
- NEMP1 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 88/149 reads (59%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.018); catalogued as COSV55664036; called by muse, mutect2, varscan2
- NET1 | c.1405C>T p.R469C (on ENST00000355029 / NM_001047160.3; = p.R415C on NM_005863.5) | Missense Mutation (SNP) | VAF 61/83 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs150542987; called by muse, mutect2, varscan2
- NIN | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV55400731; called by muse, mutect2, varscan2
- NLK | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV69410144; called by muse, mutect2, varscan2
- NLRP12 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 87/175 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100145329, COSV60751954; called by muse, mutect2, varscan2
- NLRP4 | c.518C>G p.S173W | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56709262, COSV56719853; called by muse, mutect2, varscan2
- NLRP5 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV66766495; called by muse, mutect2, varscan2
- NOD2 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs104895481, CM065051, COSV56053607; ClinVar: not provided; called by muse, mutect2, varscan2
- NPAP1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs865893523, COSV61507585; called by muse, mutect2, varscan2
- NPIPA1 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | catalogued as COSV60154909; called by muse, mutect2, varscan2
- NR1D2 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV56993172; called by muse, mutect2, varscan2
- NR3C2 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60996894; called by muse, mutect2, varscan2
- NRXN1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200781129, COSV68032996, COSV99065640; called by muse, mutect2, varscan2
- NUP133 | c.2018A>G p.N673S | Missense Mutation (SNP) | VAF 85/124 reads (69%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV54574057; called by muse, mutect2, varscan2
- NWD1 | c.2848G>A p.D950N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs564513398, COSV60338626; called by muse, mutect2, varscan2
- OR10X1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by muse, mutect2, varscan2
- OR2A12 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 94/366 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV68821794; called by muse, mutect2, varscan2
- OR2A25 | c.330A>T p.E110D | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV68717518; called by muse, mutect2, varscan2
- OR2F1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs112027056, COSV67331821; called by muse, mutect2, varscan2
- OR4A5 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.074); catalogued as COSV60523755; called by muse, mutect2, varscan2
- OR51B5 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs267602946, COSV56176675; called by muse, mutect2, varscan2
- OR52J3 | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66747533; called by muse, mutect2, varscan2
- OR5AN1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 68/95 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868511922, COSV58322024; called by muse, mutect2, varscan2
- OSBPL6 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV51916973; called by muse, mutect2, varscan2
- OXR1 | c.592C>T p.R198* (on ENST00000442977 / NM_001198532.1; = p.R197* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as COSV56333882; called by muse, mutect2, varscan2
- PC | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV63082025; called by muse, mutect2, varscan2
- PCDHA4 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV63544576; called by muse, mutect2, varscan2
- PDCD11 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV63934778; called by muse, mutect2, varscan2
- PHF8 | c.1936G>A p.E646K (on ENST00000357988 / NM_001184896.1; = p.E610K on NM_015107.3) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs782656960, COSV57682260; called by muse, mutect2, varscan2
- PIK3C2G | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs763302534, COSV56803660, COSV56832827; called by muse, mutect2, varscan2
- PIK3CG | c.2603G>A p.G868D | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV63248765, COSV63251780; called by muse, mutect2, varscan2
- PKHD1L1 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV65749308; called by muse, mutect2, varscan2
- PKHD1L1 | c.5840C>T p.S1947F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV65749313; called by muse, mutect2, varscan2
- PKN3 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.058); catalogued as COSV52576343; called by muse, mutect2, varscan2
- PLCL2 | c.1477C>T p.Q493* (on ENST00000615277 / NM_001144382.2; = p.Q367* on NM_015184.5) | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV67624098; called by muse, mutect2, varscan2
- PLEKHG1 | c.1938T>A p.F646L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV62049881; called by muse, mutect2, varscan2
- PLXND1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs867173213, COSV60717341; called by muse, mutect2, varscan2
- POF1B | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs148186919, COSV53138242; called by muse, mutect2, varscan2
- POLQ | c.5081C>T p.S1694L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV51758176; called by muse, mutect2, varscan2
- PPEF1 | c.1410A>T p.E470D | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62995788, COSV62996349; called by muse, mutect2, varscan2
- PPP1R10 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV64740089; called by muse, mutect2
- PREX2 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866647316, COSV55791015; called by muse, mutect2, varscan2
- PRRC2B | c.6034C>T p.L2012F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs772910982, COSV57645975; called by muse, mutect2, varscan2
- PSMC4 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV50096892; called by muse, mutect2, varscan2
- RAD17 | c.412C>T p.P138S (on ENST00000380774 / NM_133339.2; = p.P127S on NM_002873.1) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51458950; called by muse, mutect2, varscan2
- RAD51AP2 | c.1275A>T p.K425N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV67588727; called by muse, mutect2, varscan2
- RASAL2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752504099, COSV100862458, COSV62709448; called by muse, mutect2, varscan2
- RASD1 | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs1161650597, COSV51958129; called by muse, mutect2, varscan2
- RASGRP1 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60366845; called by muse, mutect2, varscan2
- RBM12 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58293750; called by muse, mutect2, varscan2
- RCC1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100868083, COSV65779889; called by muse, mutect2, varscan2
- RCOR2 | c.892-1G>A p.X298_splice | Splice Site (SNP) | VAF 23/32 reads (72%) | catalogued as COSV56851009; called by muse, mutect2, varscan2
- RGS9 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV52227781, COSV99287698; called by muse, mutect2, varscan2
- RNASEH2A | c.263T>G p.F88C | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV55552475; called by muse, mutect2, varscan2
- SAGE1 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as rs1479400459, COSV61015216; called by muse, mutect2, varscan2
- SALL1 | c.3900G>A p.M1300I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as rs1310266399, COSV51762042; called by muse, mutect2, varscan2
- SCAF1 | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV59192280; called by muse, mutect2, varscan2
- SCML2 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 95/183 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV52623914; called by muse, mutect2, varscan2
- SERTAD1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63596425; called by muse, mutect2, varscan2
- SETD1A | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs765710685, COSV52686219, COSV52690961; called by muse, mutect2, varscan2
- SEZ6L | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs1230881914, COSV50675277; called by muse, mutect2, varscan2
- SEZ6L | c.2156C>T p.S719L | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1307352359, COSV50658569; called by muse, mutect2, varscan2
- SGPP2 | c.346T>C p.Y116H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV58330731; called by muse, mutect2, varscan2
- SHROOM3 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.759); catalogued as rs1416217587; called by muse, mutect2, varscan2
- SIK3 | c.2960C>T p.S987L (on ENST00000445177 / NM_001366686.2; = p.S945L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/705 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as rs770197979, COSV52620594; called by muse, mutect2, varscan2
- SIPA1L2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs760458046, COSV53396433; called by muse, mutect2, varscan2
- SLC12A1 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV66798059; called by muse, mutect2, varscan2
- SLC22A16 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57932898; called by muse, mutect2, varscan2
- SLC26A4 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55918819; called by muse, mutect2, varscan2
- SLC6A8 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53472962; called by muse, varscan2
- SLC7A4 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs746953265, COSV60385384; called by muse, mutect2, varscan2
- SLC9A3R1 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52854369; called by muse, mutect2, varscan2
- SLCO4C1 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV60518798; called by muse, mutect2, varscan2
- SLITRK6 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.196); catalogued as rs772627817; called by muse, mutect2, varscan2
- SMARCA1 | c.2587C>T p.R863* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV64413192; called by muse, mutect2, varscan2
- SOX13 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs1044321748, COSV65827293; called by muse, mutect2
- SP140 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV59453299; called by muse, mutect2, varscan2
- SPTBN4 | c.5102G>A p.R1701Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58956217; called by muse, mutect2, varscan2
- SRCAP | c.5989C>T p.P1997S | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV52671529; called by muse, mutect2, varscan2
- STS | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1456154048, COSV54270720; called by muse, mutect2, varscan2
- STXBP2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs372973081, COSV55404245; called by muse, mutect2, varscan2
- STXBP5L | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56526831; called by muse, mutect2, varscan2
- STYXL2 | c.1691G>A p.G564E | Missense Mutation (SNP) | VAF 69/102 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54807781; called by muse, mutect2, varscan2
- SUGP1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV55923146; called by muse, mutect2, varscan2
- SYT4 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV54902892; called by muse, mutect2, varscan2
- SYTL4 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs772480125, COSV52165868; called by muse, varscan2
- TACR1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100538164, COSV59484492; called by muse, mutect2, varscan2
- TC2N | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs537836079, COSV61746369; called by muse, mutect2, varscan2
- TCHHL1 | c.1493G>A p.R498K | Missense Mutation (SNP) | VAF 225/328 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64284714, COSV64286831; called by muse, mutect2, varscan2
- TEP1 | c.2526G>C p.K842N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52997152; called by muse, mutect2, varscan2
- TEX10 | c.170T>G p.L57R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66517629; called by muse, varscan2
- TEX43 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64036122; called by muse, mutect2
- THBS2 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1477357959, COSV64681212; called by muse, mutect2, varscan2
- THRB | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV54981623; called by muse, mutect2, varscan2
- TIAM2 | c.5027G>A p.G1676E (on ENST00000529824; = p.G1647E on NM_012454.3) | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.995); catalogued as COSV51643247; called by muse, mutect2, varscan2
- TLR3 | c.2334A>T p.E778D | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57169781; called by muse, mutect2, varscan2
- TMEM14B | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.371); catalogued as COSV65356340; called by muse, mutect2, varscan2
- TMPRSS11E | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV59520554; called by muse, mutect2, varscan2
- TNXB | c.4454C>T p.P1485L (on ENST00000647633; = p.P1238L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/432 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs1214157253; called by muse, mutect2, varscan2
- TSPOAP1 | c.4193G>A p.G1398E | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52114773; called by muse, mutect2, varscan2
- TSR2 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757747531, COSV64309320; called by muse, varscan2
- TTC7A | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55413895; called by muse, mutect2, varscan2
- TTN | c.83039G>A p.G27680E (on ENST00000591111; = p.G20256E on NM_003319.4) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | PolyPhen probably damaging (0.976); catalogued as COSV60240121; called by muse, mutect2, varscan2
- TTN | c.72250G>A p.D24084N (on ENST00000591111; = p.D16660N on NM_003319.4) | Missense Mutation (SNP) | VAF 94/196 reads (48%) | PolyPhen probably damaging (0.996); catalogued as COSV60240152; called by muse, mutect2, varscan2
- TTN | c.39166G>A p.E13056K (on ENST00000591111; = p.E5632K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | PolyPhen probably damaging (0.994); catalogued as rs1356852922, COSV59905230; called by muse, mutect2, varscan2
- TTN | c.6388G>A p.E2130K (on ENST00000591111; = p.E2084K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | PolyPhen probably damaging (0.994); catalogued as rs762914675, COSV60092129; called by muse, mutect2, varscan2
- TUBA3D | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV58312827; called by muse, mutect2, varscan2
- UBR2 | c.2953C>T p.H985Y | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV65751722; called by muse, mutect2, varscan2
- UGT1A3 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV59393272; called by muse, mutect2, varscan2
- UGT8 | c.1029A>T p.Q343H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60419815; called by muse, mutect2, varscan2
- UNC13A | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV53192798; called by muse, mutect2, varscan2
- USP36 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.182); catalogued as rs747199387, COSV61753247; called by muse, mutect2, varscan2
- UTP14C | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as COSV73000765; called by muse, mutect2, varscan2
- UTP6 | c.189T>G p.N63K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV55574756; called by muse, mutect2, varscan2
- VARS1 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 188/407 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV100791859, COSV63304977; called by muse, mutect2, varscan2
- VIPAS39 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766112659, COSV58941318; called by muse, mutect2, varscan2
- VN1R2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59039218; called by muse, mutect2, varscan2
- VPS26A | c.659-1G>A p.X220_splice | Splice Site (SNP) | VAF 20/32 reads (63%) | catalogued as COSV54968946; called by muse, mutect2, varscan2
- VSIG8 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs1049442665, COSV100928838, COSV63653404; called by muse, mutect2, varscan2
- WDCP | c.1792C>T p.L598F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV54592499, COSV54593256; called by muse, mutect2, varscan2
- WDR24 | c.932C>T p.S311F (on ENST00000248142; = p.S181F on NM_032259.4) | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV50201354; called by muse, mutect2, varscan2
- WDR93 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.173); catalogued as COSV51534196; called by muse, mutect2, varscan2
- WIPF2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1470812106, COSV60275043; called by muse, mutect2, varscan2
- WTIP | c.820T>G p.C274G | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54329811; called by muse, mutect2, varscan2
- XIRP2 | c.4802G>A p.G1601E (on ENST00000628543; = p.G1776E on NM_152381.6) | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs921843368, COSV54722579; called by muse, mutect2, varscan2
- ZBED1 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100586053, COSV58137221; called by muse, mutect2, varscan2
- ZBTB7C | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs551094237, COSV100134553, COSV59690106; called by muse, mutect2, varscan2
- ZC3HAV1L | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV51964118; called by muse, mutect2, varscan2
- ZDHHC21 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.589); catalogued as COSV66614623; called by muse, mutect2, varscan2
- ZFR2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53601734; called by muse, mutect2, varscan2
- ZNF544 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs763373289; called by muse, mutect2
- ZNF556 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs928603770, COSV56913451; called by muse, mutect2, varscan2
- ZNF665 | c.409G>A p.G137R (on ENST00000600412; = p.G202R on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV67216612; called by muse, mutect2, varscan2
- ZNF676 | c.1201G>A p.G401R (on ENST00000650058; = p.G369R on NM_001001411.3) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs759129494, COSV68094278; called by muse, mutect2, varscan2
- ZNF749 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs745410002, COSV61945658; called by muse, mutect2, varscan2
- ZNF99 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV68056245; called by muse, mutect2, varscan2
- A2ML1 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AANAT | c.32_56del p.P11Rfs*56 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel
- BAZ2B | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- BEND4 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C2orf16 | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C5 | c.3506T>C p.I1169T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- C5 | c.3505A>G p.I1169V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC81 | c.1727_1736del p.V576Afs*15 (on ENST00000445632 / NM_001156474.2; = p.V486Afs*15 on NM_021827.4) | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | called by mutect2, pindel, varscan2
- CFTR | c.1351G>C p.G451R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A5 | c.2395G>A p.G799S | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DDHD1 | c.1316C>T p.P439L (on ENST00000323669; = p.P636L on NM_030637.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDHD1 | c.1315C>T p.P439S (on ENST00000323669; = p.P636S on NM_030637.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAAF6 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DNAAF6 | c.359T>A p.V120E | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FAM81A | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.11912A>C p.Q3971P | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GSDMC | c.26del p.S9Tfs*13 | Frame Shift Del (DEL) | VAF 26/107 reads (24%) | called by mutect2, pindel, varscan2
- IL16 | c.2272C>T p.P758S (on ENST00000302987 / NM_172217.5; = p.P57S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- JMJD4 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRRC2B | c.4255A>T p.R1419W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHROOM3 | c.1262G>A p.G421D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLITRK6 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SRCIN1 | c.575G>A p.R192K (on ENST00000621492; = p.R158K on NM_025248.3) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- ZNF544 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- A2ML1 | c.1173G>A p.L391= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as rs75353365; called by muse, mutect2, varscan2
- AASDH | c.2694C>T p.V898= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV52705893, COSV52708987; called by muse, mutect2, varscan2
- ABCG1 | c.720C>T p.F240= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs779081963, COSV59202069; called by muse, mutect2, varscan2
- ABHD4 | c.105C>T p.I35= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV53530352; called by muse, mutect2, varscan2
- AC109583.1 | c.1014G>A p.E338= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV58406291; called by muse, mutect2, varscan2
- ACACB | c.1896C>T p.P632= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs1387760140, COSV58142059; called by muse, mutect2, varscan2
- ACP7 | c.1167C>T p.A389= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs142073546, COSV58700393; called by muse, varscan2
- ADCY7 | c.1488C>T p.P496= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as rs948174925, COSV54269481; called by muse, varscan2
- ADGRF5 | c.2739C>T p.I913= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs779097361, COSV51938005; called by muse, mutect2, varscan2
- ADGRG4 | c.6678C>T p.S2226= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV54963278; called by muse, mutect2, varscan2
- AFM | c.834C>T p.I278= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs773785430, COSV56921434; called by muse, mutect2, varscan2
- AHNAK2 | c.3438G>A p.E1146= | Silent (SNP) | VAF 83/289 reads (29%) | catalogued as COSV60924495; called by muse, mutect2, varscan2
- ALDOB | c.297G>A p.K99= | Silent (SNP) | VAF 135/348 reads (39%) | catalogued as COSV66397983; called by muse, mutect2, varscan2
- ANAPC2 | c.1041C>T p.I347= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs770478992, COSV59244990, COSV59245664; called by muse, mutect2, varscan2
- ANK3 | c.5028G>A p.K1676= | Silent (SNP) | VAF 46/60 reads (77%) | catalogued as COSV55073324; called by muse, mutect2, varscan2
- ANKRD49 | c.597C>T p.Y199= | Silent (SNP) | VAF 44/61 reads (72%) | catalogued as rs371935415; called by muse, mutect2, varscan2
- ARHGAP19 | c.1032C>T p.S344= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV57394866; called by muse, mutect2, varscan2
- ARHGAP36 | c.1062C>T p.I354= | Silent (SNP) | VAF 79/314 reads (25%) | catalogued as COSV52270207; called by muse, mutect2, varscan2
- ARHGEF18 | c.1329C>T p.L443= (on ENST00000359920 / NM_001130955.2; = p.L339= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs746987704, COSV60471094; called by muse, mutect2, varscan2
- ARHGEF4 | c.225G>A p.Q75= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs773849907, COSV58127169; called by muse, mutect2, varscan2
- ARHGEF5 | c.4569C>T p.P1523= | Silent (SNP) | VAF 42/181 reads (23%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.483G>A p.P161= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs749163611, COSV56235474; called by muse, mutect2, varscan2
- ARSF | c.1599G>A p.K533= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV63840573; called by muse, mutect2, varscan2
- ARSJ | c.771G>A p.K257= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1227242550, COSV59538927; called by muse, mutect2, varscan2
- ATP8B3 | c.3744C>T p.R1248= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59546425; called by muse, mutect2, varscan2
- BAHCC1 | c.7470C>T p.P2490= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV57031198; called by muse, mutect2, varscan2
- BEND4 | c.1311G>A p.R437= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, varscan2
- BRD4 | c.3378C>T p.S1126= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV54591623; called by muse, mutect2, varscan2
- BRSK2 | c.1398C>T p.S466= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1394639912, COSV57546815; called by muse, varscan2
- C2orf16 | c.2670C>T p.S890= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV62679002; called by muse, mutect2, varscan2
- CACNA1B | c.1713C>T p.S571= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1307159981, COSV53134993; called by muse, mutect2, varscan2
- CACNA1H | c.4017C>T p.F1339= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs766859067, COSV61984884; called by muse, mutect2, varscan2
- CACNA2D3 | c.3075C>T p.I1025= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- CCDC144A | c.87C>T p.V29= | Silent (SNP) | VAF 25/43 reads (58%) | catalogued as COSV61404078; called by muse, mutect2, varscan2
- CCDC150 | c.210C>T p.D70= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV55877060; called by muse, mutect2, varscan2
- CCDC158 | c.2961G>A p.R987= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV66356845; called by muse, mutect2, varscan2
- CCDC178 | c.732T>C p.H244= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV55788679; called by muse, mutect2, varscan2
- CCDC63 | c.1557C>T p.P519= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV57407766; called by muse, mutect2, varscan2
- CCNJL | c.456C>T p.P152= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV57446110; called by muse, mutect2, varscan2
- CD200 | c.27A>G p.T9= | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as COSV59864144; called by muse, mutect2, varscan2
- CDK5R2 | c.978G>A p.K326= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs959117952, COSV56937082; called by muse, mutect2
- CFAP65 | c.1497C>T p.F499= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV55391181; called by muse, mutect2, varscan2
- CHST6 | c.63C>T p.L21= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1363023147, COSV60001239; called by muse, mutect2, varscan2
- CLNK | c.66C>T p.F22= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV57019114; called by muse, mutect2, varscan2
- CNBD2 | c.318C>T p.A106= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as rs201820579, COSV100839102, COSV62587660; called by muse, mutect2, varscan2
- COL6A6 | c.3603G>A p.Q1201= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV62030309, COSV62032955; called by muse, mutect2, varscan2
- CORO7 | c.141C>T p.F47= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV52032725; called by muse, mutect2
- CREB3L3 | c.1143C>T p.A381= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as COSV50243257; called by muse, mutect2, varscan2
- CSK | c.1143C>T p.S381= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV54975225; called by muse, mutect2, varscan2
- CSMD1 | c.2736C>T p.L912= (on ENST00000520002; = p.L911= on NM_033225.6) | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs186256974, COSV59359946; called by muse, mutect2, varscan2
- CTDP1 | c.1383C>T p.S461= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV50007290; called by muse, mutect2, varscan2
- CYP1A2 | c.501G>A p.K167= | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as rs1332811682, COSV59659983; called by muse, mutect2, varscan2
- CYP4F2 | c.930G>A p.G310= | Silent (SNP) | VAF 67/262 reads (26%) | catalogued as rs955558445, COSV50002176; called by muse, mutect2, varscan2
- CYTH2 | c.612C>T p.V204= | Silent (SNP) | VAF 38/96 reads (40%) | called by muse, mutect2, varscan2
- DAB2 | c.1632C>T p.V544= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV57917341; called by muse, mutect2, varscan2
- DCAF4L1 | c.1104C>T p.F368= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs751949363, COSV60786749; called by muse, mutect2, varscan2
- DDX51 | c.1026C>T p.I342= | Silent (SNP) | VAF 34/65 reads (52%) | catalogued as rs368452269, COSV100223025; called by muse, mutect2, varscan2
- DISP3 | c.1198C>T p.L400= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV53821037, COSV53834239; called by muse, mutect2, varscan2
- DLEC1 | c.438G>A p.L146= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as rs917102248, COSV57304208; called by muse, mutect2, varscan2
- DMXL2 | c.6309C>T p.S2103= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV51852233; called by muse, mutect2, varscan2
- DOCK10 | c.891C>T p.L297= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs1214631822, COSV51423196; called by muse, mutect2, varscan2
- DRD2 | c.573C>T p.V191= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs961789208, COSV60761052; called by muse, mutect2, varscan2
- DSG4 | c.1989G>A p.L663= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as rs763071841, COSV57395269; called by muse, mutect2, varscan2
- DUSP15 | c.468C>T p.C156= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1212513721, COSV54067673; called by muse, mutect2, varscan2
- EEF1G | c.1038C>T p.F346= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV61322820; called by muse, mutect2, varscan2
- ERICH3 | c.2067G>A p.G689= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as rs1433150465, COSV58614053; called by muse, mutect2, varscan2
- FAT2 | c.3966G>T p.G1322= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55826164; called by muse, mutect2, varscan2
- FAT3 | c.4281C>T p.S1427= | Silent (SNP) | VAF 113/335 reads (34%) | catalogued as COSV53153411; called by muse, mutect2, varscan2
- FAT4 | c.9159G>A p.L3053= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV58700754; called by muse, mutect2, varscan2
- FBN1 | c.2874C>T p.C958= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV57325893; called by muse, mutect2, varscan2
- FBN1 | c.1452C>T p.L484= | Silent (SNP) | VAF 48/70 reads (69%) | catalogued as COSV57325902; called by muse, mutect2, varscan2
- FCRL3 | c.1275G>A p.G425= | Silent (SNP) | VAF 37/199 reads (19%) | catalogued as COSV63843232; called by muse, mutect2, varscan2
- FEM1A | c.1314C>T p.F438= | Silent (SNP) | VAF 69/218 reads (32%) | catalogued as COSV54164549; called by muse, mutect2, varscan2
- FGFR2 | c.960G>A p.T320= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs768112524, COSV60643553, COSV60655165; called by muse, varscan2
- FPR3 | c.534C>T p.F178= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as COSV59331309; called by muse, mutect2, varscan2
- GAS2L2 | c.2349G>A p.R783= | Silent (SNP) | VAF 48/216 reads (22%) | called by muse, varscan2
- GLP1R | c.1074C>T p.P358= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV64716017; called by muse, mutect2, varscan2
- GPA33 | c.528G>A p.K176= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV63301854; called by muse, mutect2, varscan2
- GRIK3 | c.2064G>A p.K688= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs764944055, COSV66144264; called by muse, mutect2, varscan2
- GSDMB | c.642C>T p.F214= | Silent (SNP) | VAF 116/240 reads (48%) | catalogued as COSV58782042; called by muse, mutect2, varscan2
- HELZ2 | c.5961C>T p.F1987= (on ENST00000467148 / NM_001037335.2; = p.F1418= on NM_033405.3) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV71296634; called by muse, mutect2, varscan2
- HMCN1 | c.11853A>G p.A3951= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV54926206; called by muse, mutect2, varscan2
- HSPBP1 | c.943C>T p.L315= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV55335017; called by muse, mutect2, varscan2
- HYDIN | c.5472G>A p.L1824= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99993361; called by muse, mutect2
- HYDIN | c.4341C>T p.I1447= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV66833657; called by muse, mutect2, varscan2
- ICA1L | c.9C>T p.S3= | Silent (SNP) | VAF 131/453 reads (29%) | catalogued as rs1276877113, COSV64174235; called by muse, mutect2, varscan2
- IFIH1 | c.1815G>A p.R605= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV55128860; called by muse, mutect2, varscan2
- IGHV3-23 | c.330G>A p.T110= | Silent (SNP) | VAF 46/347 reads (13%) | catalogued as rs782338253; called by muse, mutect2, varscan2
- IGHV5-51 | c.183G>A p.G61= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs782605128; called by muse, mutect2, varscan2
- IL16 | c.2271C>T p.T757= (on ENST00000302987 / NM_172217.5; = p.T56= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- IL6R | c.894C>T p.F298= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs762649480, COSV59818301; called by muse, mutect2, varscan2
- JAG1 | c.2901G>A p.K967= | Silent (SNP) | VAF 100/182 reads (55%) | catalogued as rs780648241, COSV54760828; called by muse, mutect2, varscan2
- KCNB2 | c.756C>T p.F252= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV73051828; called by muse, mutect2, varscan2
- KCNU1 | c.3393G>A p.R1131= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs759100554, COSV67758642; called by muse, mutect2, varscan2
- KIF1C | c.3015C>T p.P1005= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV100297127, COSV57906101; called by muse, mutect2, varscan2
- LARS2 | c.1557G>A p.T519= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as rs751609685, COSV55530410, COSV55531239; called by muse, mutect2, varscan2
- LCT | c.1845G>A p.E615= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs200913371, COSV51554744; called by muse, mutect2, varscan2
- LILRA1 | c.658C>T p.L220= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV52183405; called by muse, mutect2, varscan2
- LILRB1 | c.300G>A p.K100= (on ENST00000427581; = p.K64= on NM_006669.6) | Silent (SNP) | VAF 48/211 reads (23%) | catalogued as COSV100207043; called by muse, mutect2
- MAN2B2 | c.2403C>T p.F801= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs746568293, COSV53450749; called by muse, mutect2, varscan2
- MAST1 | c.1626C>T p.F542= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV52251808; called by muse, mutect2, varscan2
- MED13 | c.3039G>A p.R1013= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV67261902, COSV67265877; called by muse, mutect2, varscan2
- MEX3C | c.867C>T p.A289= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- MGAM | c.3009C>T p.Y1003= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as rs558423138, COSV72075272; called by muse, mutect2, varscan2
- MIER2 | c.501C>T p.F167= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as rs748138053, COSV53397437; called by muse, mutect2, varscan2
- MIGA2 | c.1599G>A p.R533= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV52978031; called by muse, mutect2, varscan2
- MKRN3 | c.960G>A p.E320= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV58811393; called by muse, mutect2, varscan2
- MMP15 | c.765G>A p.L255= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV54680894; called by muse, mutect2, varscan2
- MOSPD2 | c.378G>A p.K126= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV66860576; called by muse, mutect2, varscan2
- MTAP | c.147G>A p.K49= | Silent (SNP) | VAF 103/135 reads (76%) | catalogued as COSV66476822; called by muse, mutect2, varscan2
- MYH1 | c.5151T>C p.V1717= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV56854118; called by muse, mutect2, varscan2
- MYH1 | c.4251C>T p.S1417= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs767249904, COSV56854124; called by muse, mutect2, varscan2
- MYH2 | c.3468G>A p.L1156= | Silent (SNP) | VAF 53/183 reads (29%) | catalogued as COSV55440812; called by muse, mutect2, varscan2
- NEK2 | c.1077G>A p.K359= | Silent (SNP) | VAF 78/129 reads (60%) | called by muse, mutect2, varscan2
- NFATC3 | c.2058G>A p.K686= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as rs753136816, COSV60477480; called by muse, mutect2, varscan2
- NLRP1 | c.795C>T p.S265= | Silent (SNP) | VAF 58/232 reads (25%) | catalogued as COSV52573820; called by muse, mutect2, varscan2
- NRXN2 | c.2592C>T p.I864= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs919153063, COSV55460294; called by mutect2, varscan2
- NXPE4 | c.1167G>A p.R389= (on ENST00000375478 / NM_001077639.2; = p.R105= on NM_017678.3) | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as COSV64944180; called by muse, mutect2
- OR1E1 | c.144C>T p.L48= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs1025990973, COSV59459474; called by muse, mutect2, varscan2
- OR2B2 | c.312C>T p.F104= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV57580421; called by muse, mutect2, varscan2
- OR4N5 | c.111C>T p.I37= | Silent (SNP) | VAF 103/220 reads (47%) | catalogued as COSV61319958; called by muse, mutect2, varscan2
- OR52L1 | c.753C>T p.A251= | Silent (SNP) | VAF 71/103 reads (69%) | catalogued as rs762731500, COSV59988435; called by muse, mutect2, varscan2
- OR5L2 | c.831C>T p.F277= | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as rs868088262, COSV65723527, COSV65724863; called by muse, mutect2, varscan2
- OXCT2 | c.966C>T p.I322= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs762123479, COSV100560352; called by muse, varscan2
- P4HA1 | c.591C>G p.G197= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV54960120, COSV54964078; called by muse, mutect2, varscan2
- PCDH19 | c.1509C>T p.F503= | Silent (SNP) | VAF 84/156 reads (54%) | catalogued as COSV55264807; called by muse, mutect2, varscan2
- PCDHB16 | c.801G>A p.R267= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as rs959267929, COSV53368065; called by muse, mutect2, varscan2
- PCLO | c.9735C>T p.F3245= | Silent (SNP) | VAF 72/117 reads (62%) | catalogued as rs1356343508, COSV61655270; called by muse, mutect2, varscan2
- PCP4L1 | c.168C>T p.F56= | Silent (SNP) | VAF 57/82 reads (70%) | catalogued as COSV73440736, COSV73440796; called by muse, mutect2, varscan2
- PDE1C | c.1479G>A p.P493= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs777008870, COSV58508026; called by muse, mutect2, varscan2
- PDZD4 | c.2226C>T p.T742= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as rs926733236, COSV51249373; called by muse, mutect2, varscan2
- PHC2 | c.168C>T p.T56= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs769943135, COSV57106610; called by muse, mutect2, varscan2
- PKD2L1 | c.90C>T p.S30= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV58397897; called by muse, mutect2, varscan2
- PLVAP | c.402T>C p.A134= | Silent (SNP) | VAF 55/219 reads (25%) | catalogued as COSV53086787; called by muse, mutect2, varscan2
- POGLUT1 | c.255A>T p.L85= | Silent (SNP) | VAF 80/135 reads (59%) | catalogued as COSV55157839; called by muse, mutect2, varscan2
- POLG | c.735C>T p.I245= | Silent (SNP) | VAF 44/72 reads (61%) | catalogued as rs778281076, COSV51523833; called by muse, mutect2, varscan2
- PPP2R2B | c.735G>A p.G245= (on ENST00000394409; = p.G311= on NM_181674.2) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV60773388; called by muse, mutect2, varscan2
- PRND | c.114G>A p.K38= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as COSV59897077; called by muse, mutect2, varscan2
- PRPS2 | c.810C>T p.V270= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs775666543, COSV66180036; called by muse, mutect2, varscan2
- PUS7 | c.780C>T p.F260= | Silent (SNP) | VAF 41/187 reads (22%) | catalogued as rs892248347, COSV62677675; called by muse, mutect2, varscan2
- RANBP9 | c.1047C>T p.I349= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as rs267600840, COSV50584211; called by muse, mutect2, varscan2
- RASGRF1 | c.588C>A p.P196= | Silent (SNP) | VAF 41/78 reads (53%) | catalogued as COSV69179798; called by muse, mutect2, varscan2
- RIN3 | c.2952C>T p.F984= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1162036335, COSV53653397; called by muse, mutect2, varscan2
- RMI2 | c.330C>T p.A110= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as rs774922318, COSV56964329; called by muse, mutect2, varscan2
- RSF1 | c.3678C>T p.S1226= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as COSV57843784; called by muse, mutect2
- RTL5 | c.1080G>A p.K360= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV65454427; called by muse, mutect2, varscan2
- RWDD2B | c.222G>A p.K74= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV54502056; called by muse, mutect2, varscan2
- S1PR3 | c.256C>T p.L86= | Silent (SNP) | VAF 80/103 reads (78%) | catalogued as COSV63981155; called by muse, mutect2, varscan2
- SAMD9L | c.3033T>C p.I1011= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV59082932; called by muse, mutect2, varscan2
- SEC14L5 | c.1419C>T p.F473= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs750265372, COSV52036857; called by muse, mutect2, varscan2
- SERTM1 | c.144C>T p.F48= | Silent (SNP) | VAF 106/214 reads (50%) | catalogued as rs1251861251, COSV59376226; called by muse, mutect2, varscan2
- SH3GLB2 | c.366A>G p.E122= | Silent (SNP) | VAF 62/158 reads (39%) | catalogued as COSV65331600; called by muse, mutect2, varscan2
- SLC12A8 | c.1971C>T p.L657= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV58869004; called by muse, mutect2, varscan2
- SLC30A3 | c.255C>T p.V85= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as COSV51987074; called by muse, mutect2, varscan2
- SLC39A5 | c.405G>A p.S135= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs772358783, COSV57190466; called by muse, mutect2, varscan2
- SLC44A5 | c.513G>A p.A171= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs762534368, COSV63762599; called by muse, mutect2, varscan2
- SPAG17 | c.5901G>A p.Q1967= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV60464567; called by muse, mutect2, varscan2
- SPAG17 | c.4464G>A p.V1488= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs551770538, COSV60464571; called by muse, mutect2, varscan2
- SPTBN2 | c.1590C>T p.N530= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as COSV59458331; called by muse, mutect2, varscan2
- SRPK1 | c.948C>T p.P316= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs771145508, COSV100644492, COSV60414953; called by muse, mutect2, varscan2
- STAB1 | c.2175C>T p.F725= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs148343623, COSV58736773; called by muse, mutect2, varscan2
- STYXL2 | c.3102G>A p.E1034= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV54808439; called by muse, mutect2, varscan2
- SULF1 | c.984G>A p.K328= | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as COSV52685070, COSV52688939; called by muse, mutect2, varscan2
- SUN1 | c.447C>T p.F149= (on ENST00000405266 / NM_001367651.1; = p.F99= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV61779063; called by muse, mutect2, varscan2
- SV2C | c.1389C>T p.S463= | Silent (SNP) | VAF 77/135 reads (57%) | catalogued as rs753076461, COSV59225870; called by muse, mutect2, varscan2
- SVOPL | c.1116G>A p.L372= (on ENST00000419765; = p.L220= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV55993987; called by muse, mutect2, varscan2
- SYNE1 | c.19248C>T p.L6416= (on ENST00000367255 / NM_182961.4; = p.L6345= on NM_033071.3) | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV55009964; called by muse, mutect2, varscan2
- SYT3 | c.708G>A p.Q236= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV58898235; called by muse, mutect2, varscan2
- SYVN1 | c.279C>T p.T93= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as rs563052487, COSV53696653; called by muse, mutect2, varscan2
- TENM3 | c.7779C>T p.F2593= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs750129800, COSV69308752; called by mutect2, varscan2
- TEX14 | c.312C>T p.I104= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV53623105; called by muse, varscan2
- TEX47 | c.24G>A p.Q8= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as COSV51878470, COSV51879802; called by muse, mutect2, varscan2
- TFCP2L1 | c.1290C>T p.H430= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs767673093, COSV55293851; called by muse, mutect2, varscan2
- THEMIS | c.69C>T p.I23= | Silent (SNP) | VAF 60/85 reads (71%) | catalogued as COSV64072042; called by muse, mutect2, varscan2
- TMEM184B | c.603G>A p.R201= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as COSV62673533; called by muse, mutect2, varscan2
- TMEM200A | c.420C>T p.F140= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV51656990; called by muse, mutect2, varscan2
- TNRC18 | c.8619G>A p.Q2873= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1270663105, COSV60308842; called by muse, mutect2
- TNXB | c.4455C>T p.P1485= (on ENST00000647633; = p.P1238= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 165/427 reads (39%) | catalogued as rs1486499004; called by muse, mutect2, varscan2
- TP53AIP1 | c.24C>T p.S8= | Silent (SNP) | VAF 44/66 reads (67%) | catalogued as rs1299862031, COSV71688851; called by muse, mutect2, varscan2
- TRHR | c.981C>T p.F327= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs267601710, COSV61233373; called by muse, mutect2, varscan2
- TRIM31 | c.1062T>A p.S354= | Silent (SNP) | VAF 90/247 reads (36%) | catalogued as COSV65060085; called by muse, mutect2, varscan2
- TRIM46 | c.900G>A p.R300= | Silent (SNP) | VAF 73/107 reads (68%) | catalogued as rs1203078637, COSV55279865; called by muse, mutect2, varscan2
- TRIM65 | c.933C>T p.P311= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV53934336; called by muse, mutect2
- TRIM67 | c.1338G>A p.E446= | Silent (SNP) | VAF 104/179 reads (58%) | catalogued as rs1336091983, COSV64158185, COSV64159712; called by muse, mutect2, varscan2
- UGT2B10 | c.1485C>T p.F495= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV55322387; called by muse, mutect2, varscan2
- UPF3B | c.93G>A p.G31= | Silent (SNP) | VAF 128/231 reads (55%) | catalogued as rs750093901, COSV52231013; called by muse, mutect2, varscan2
- VGLL1 | c.561G>A p.R187= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as COSV65703661; called by muse, mutect2, varscan2
- VPS18 | c.226C>T p.L76= | Silent (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- VPS8 | c.4248C>T p.F1416= (on ENST00000625842 / NM_001349294.1; = p.F1414= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs776853029, COSV54992812; called by muse, mutect2, varscan2
- VWA7 | c.2541C>T p.L847= | Silent (SNP) | VAF 205/481 reads (43%) | catalogued as rs757194132, COSV65173912; called by muse, mutect2, varscan2
- WASL | c.717T>C p.C239= | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as COSV56135322; called by muse, mutect2, varscan2
- WDR90 | c.1980C>G p.P660= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV53466142, COSV53473513; called by muse, mutect2, varscan2
- WFS1 | c.285C>T p.A95= | Silent (SNP) | VAF 71/231 reads (31%) | catalogued as COSV56990709; called by muse, mutect2, varscan2
- WRN | c.192C>T p.F64= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs1374804871, COSV53299934; called by muse, mutect2, varscan2
- ZBTB21 | c.1491A>G p.L497= | Silent (SNP) | VAF 76/164 reads (46%) | catalogued as COSV60405239; called by muse, mutect2, varscan2
- ZCCHC4 | c.30C>T p.A10= | Silent (SNP) | VAF 68/165 reads (41%) | catalogued as rs746189830, COSV100255414, COSV57182757; called by muse, mutect2, varscan2
- ZNF222 | c.1296G>A p.K432= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV51827818; called by muse, mutect2, varscan2
- ZNF616 | c.1617T>C p.H539= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV57512644; called by muse, mutect2, varscan2
- ZNF749 | c.1527G>A p.R509= | Silent (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- ZNF831 | c.142C>T p.L48= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV64042166; called by muse, mutect2, varscan2
- AC024940.1 | n.330C>T | RNA (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824068 T>A | 5'Flank (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- ANK1 | c.5395-1192G>A | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2
- ASTN1 | c.1120+198C>T | Intron (SNP) | VAF 12/18 reads (67%) | catalogued as rs754129872, COSV99921037; called by muse, varscan2
- DLG3 | c.1145+678C>T | Intron (SNP) | VAF 8/35 reads (23%) | catalogued as COSV52082720, COSV99529806; called by muse, mutect2, varscan2
- IL1RAPL2 | c.*2G>A | 3'UTR (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100781739; called by muse, mutect2, varscan2
- MIR509-2 | n.17C>T | RNA (SNP) | VAF 36/182 reads (20%) | called by muse, mutect2, varscan2
- NACA | c.71-2658C>T | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs748934762; called by mutect2, varscan2
- NGB | c.*277G>A | 3'UTR (SNP) | VAF 14/79 reads (18%) | catalogued as rs749945214, COSV53611483; called by muse, mutect2, varscan2
- PKD1L2 | n.347G>A | RNA (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- PLCE1 | c.1207-43054G>A | Intron (SNP) | VAF 33/47 reads (70%) | catalogued as COSV99593331; called by muse, mutect2, varscan2
- PLD1 | c.2882+666C>T | Intron (SNP) | VAF 12/53 reads (23%) | catalogued as rs543887304, COSV60575786; called by muse, mutect2, varscan2
- SLCO1A2 | c.61-469G>A | Intron (SNP) | VAF 65/120 reads (54%) | catalogued as rs1428618995, COSV100261431; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23975G>A | Intron (SNP) | VAF 47/163 reads (29%) | catalogued as rs867794966, COSV67444095; called by muse, mutect2, varscan2
- TFE3 | c.*385A>T | 3'UTR (SNP) | VAF 66/120 reads (55%) | catalogued as COSV100252733; called by muse, mutect2, varscan2
- UPRT | c.429+1095C>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- USH1C | c.1284+7575C>T | Intron (SNP) | VAF 61/93 reads (66%) | called by muse, mutect2, varscan2
- ZNF99 | c.*598G>A | 3'UTR (SNP) | VAF 14/56 reads (25%) | catalogued as rs540238009, COSV101233869; called by muse, varscan2
